Somatic mutation profile of tumor specimen 0DODO0 from CCDI case PBCBZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.7 years (2,094 days).
Specimen 0DODO0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c06e6aed-2538-407a-9a41-08a50d180669.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DODM8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a57ad5a7-e6cb-4dbb-a861-956e3bb1a444

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 13, Intron 7, Nonsense Mutation 3, 5'Flank 2, 5'UTR 2, In Frame Del 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 122/258 reads (47%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 155/221 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ADCY8 | c.2721G>A p.M907I | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as rs1306586517; called by muse, mutect2
- CFHR5 | c.1116C>A p.N372K | Missense Mutation (SNP) | VAF 162/354 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs556270179, COSV56829596; called by muse, varscan2
- CLSPN | c.1190G>T p.C397F | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.178); catalogued as rs1288335243; called by muse, mutect2, varscan2
- CNTN4 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs377113483, COSV68561748; called by muse, varscan2
- COLEC12 | c.2073A>C p.K691N | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV68369055; called by muse, mutect2, varscan2
- CREBBP | c.4232G>A p.G1411E | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201186078, COSV52116481, COSV52117966; called by muse, mutect2, varscan2
- GLIS3 | c.2227G>C p.G743R | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs771158269, COSV60928273; called by muse, mutect2, varscan2
- PCDHB1 | c.2092C>A p.L698I | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV60630855, COSV60631086; called by muse, mutect2, varscan2
- PPFIBP2 | c.1604G>C p.G535A | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55077785; called by muse, mutect2, varscan2
- SEMA5B | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52092038; called by muse, mutect2, varscan2
- SLC4A2 | c.1076G>C p.R359P | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV59657467; called by muse, mutect2, varscan2
- SOX5 | c.1630A>G p.R544G | Missense Mutation (SNP) | VAF 80/438 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58630792; called by muse, mutect2, varscan2
- SPACA1 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV52760885; called by muse, mutect2, varscan2
- SPG21 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.171); catalogued as rs587777315, CM143544; called by muse, mutect2, varscan2
- SPIRE2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344216110, COSV65555704; called by muse, mutect2, varscan2
- TTN | c.58012G>C p.E19338Q (on ENST00000591111; = p.E11914Q on NM_003319.4) | Missense Mutation (SNP) | VAF 84/324 reads (26%) | PolyPhen probably damaging (0.997); catalogued as rs1306891128, COSV59906544; called by muse, mutect2, varscan2
- VPS37B | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 18/317 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1420713678; called by muse, mutect2
- ZCCHC12 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 86/89 reads (97%) | catalogued as COSV59571414; called by muse, mutect2, varscan2
- ZFHX4 | c.1653C>G p.N551K | Missense Mutation (SNP) | VAF 103/529 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV99256482; called by muse, mutect2, varscan2
- ZNF23 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV61840577; called by muse, mutect2
- ZNF548 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs765147590; called by muse, mutect2, varscan2
- A2M | c.789T>G p.H263Q | Missense Mutation (SNP) | VAF 128/577 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA9 | c.2502A>T p.K834N | Missense Mutation (SNP) | VAF 350/583 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGAP2 | c.3340G>C p.G1114R (on ENST00000547588 / NM_001122772.2; = p.G758R on NM_014770.4) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ALOXE3 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CACNA1C | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CATSPERB | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COL14A1 | c.3208A>T p.T1070S | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYGS | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTNNA1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.026); called by muse, varscan2
- DEF6 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FAM136A | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 110/337 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- FANCD2 | c.3539A>C p.D1180A | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2
- FCRL4 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- FEM1A | c.186C>A p.D62E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GABRG2 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GBP2 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPRIN2 | c.1222C>G p.Q408E | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HECTD1 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KCNK9 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LDLR | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LEPR | c.3203C>A p.P1068H | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MARCHF9 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MGA | c.7873G>T p.E2625* (on ENST00000219905 / NM_001164273.1; = p.E2416* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 136/295 reads (46%) | called by muse, mutect2, varscan2
- OR10A6 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52E5 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP12 | c.173C>G p.A58G | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB2 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PIP5K1B | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLXNA1 | c.1895A>G p.Q632R | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- POC5 | c.976-1G>T p.X326_splice (on ENST00000428202 / NM_001099271.2; = p.X301_splice on NM_152408.2) | Splice Site (SNP) | VAF 198/764 reads (26%) | called by muse, mutect2, varscan2
- RRN3 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC17A2 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SPATA20 | c.1891C>T p.P631S (on ENST00000356488 / NM_001258372.1; = p.P647S on NM_022827.4) | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SUCNR1 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 36/613 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.056); called by muse, mutect2
- SYNJ2 | c.2602del p.E868Kfs*26 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, varscan2
- TCHHL1 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TNR | c.705C>A p.C235* | Nonsense Mutation (SNP) | VAF 64/149 reads (43%) | called by muse, mutect2, varscan2
- TSPY1 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by mutect2, varscan2
- USP29 | c.2491C>A p.H831N | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZNF543 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 118/319 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM6 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 102/357 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CARD6 | c.1014G>C p.V338= | Silent (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.1017T>G p.A339= | Silent (SNP) | VAF 72/1220 reads (6%) | called by muse, mutect2
- FOXD4L3 | c.774C>A p.R258= | Silent (SNP) | VAF 40/246 reads (16%) | called by muse, varscan2
- HLTF | c.555T>C p.G185= | Silent (SNP) | VAF 172/594 reads (29%) | catalogued as rs150121871; called by muse, mutect2, varscan2
- HMX2 | c.57C>T p.S19= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as rs922526704; called by muse, mutect2, varscan2
- HSPG2 | c.10047G>C p.L3349= | Silent (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- MELTF | c.1248C>T p.D416= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs141115556; called by muse, mutect2, varscan2
- NDUFAF5 | c.232C>A p.R78= | Silent (SNP) | VAF 86/559 reads (15%) | catalogued as COSV99176425; called by muse, mutect2, varscan2
- PCDHB12 | c.585T>G p.V195= | Silent (SNP) | VAF 188/294 reads (64%) | called by muse, varscan2
- SIGLEC5 | c.1482C>A p.P494= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as COSV99706914; called by muse, mutect2, varscan2
- USP2 | c.600G>A p.E200= | Silent (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- WDR72 | c.564T>C p.D188= | Silent (SNP) | VAF 85/194 reads (44%) | called by muse, mutect2, varscan2
- ZNF536 | c.408C>A p.G136= | Silent (SNP) | VAF 67/225 reads (30%) | called by muse, mutect2, varscan2
- ARMH4 | c.1831+15055A>G | Intron (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- CACNA1C | c.3829-606C>T | Intron (SNP) | VAF 49/315 reads (16%) | catalogued as rs776471522; called by muse, mutect2, varscan2
- DHPS | c.889-24C>T | Intron (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- DUSP22 | c.435+67C>T | Intron (SNP) | VAF 11/80 reads (14%) | catalogued as rs573123014; called by muse, mutect2, varscan2
- ELP2 | c.2211-77G>C | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- GABRG2 | c.*34C>G | 3'UTR (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- KIT | c.2484+82C>T | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- LINGO2 | c.-29G>A | 5'UTR (SNP) | VAF 75/200 reads (38%) | called by muse, mutect2, varscan2
- OR13A1 | c.-63A>G | 5'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- OTUD6B | chr8:91070259 C>G | 5'Flank (SNP) | VAF 63/259 reads (24%) | called by muse, mutect2, varscan2
- SCNN1A | chr12:6377159 G>T | 5'Flank (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- SRRM3 | c.1008+59G>C | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
